Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01C, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01C-01A (Primary Tumor).

TCGA #: _____ Sample ID #: _____

Diagnosis:

Right hemicolectomy preparation tumor-free resection margins, several tubular colon adenomas of the mucous membrane with up to moderate dysplasia (synonymous: mild intraepithelial neoplasia), with several more recent mucosal ulcerations and displaying status post excision of further adenomas of the colon mucosa (compare previous findings xxxxxxxxxxxx and xxxxxxxxxxxx) and with inclusion of a colorectal double carcinoma characterized as an ulcerated, moderately differentiated type of adenocarcinoma in the ascending colon and in the transverse colon (8 cm and 29 cm aborally of the ileocecal valve), both with invasion of the lamina muscularis propria, and with invasion of the lymphatic vessels and with a total of three local lymph node metastases (G2, pT2 L1, V0 R0, pN1 3/21).

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: ascending colon C18.2

for 3/30/11

Source: NCI Genomic Data Commons file 9f30a93b-85bf-40e4-b41e-6bb9d91ca0ca (TCGA-AA-A01C.DDD08E2A-031B-4488-B96B-74697603B470.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).